Somatic mutation profile of tumor specimen 0DW8GT from CCDI case PBCLBA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Adenoid cystic carcinoma; Tissue or organ of origin: Parotid gland; Age at diagnosis: 15.7 years (5,737 days).
Specimen 0DW8GT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e8c00a5-f000-4ade-af40-ca7e0777e110.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DW8GH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30631a40-f9d0-44e1-b175-03154375d602

The open-access MAF lists 14 somatic variants for this specimen: 7 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 6, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 89/824 reads (11%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANPEP | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 44/261 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs764320169; called by muse, mutect2, varscan2
- MAP3K12 | c.2294G>A p.S765N | Missense Mutation (SNP) | VAF 68/483 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.108); catalogued as rs777499700; called by muse, mutect2, varscan2
- NDUFB5 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 76/754 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV52019909; called by muse, mutect2
- ST8SIA3 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 117/871 reads (13%) | PolyPhen possibly damaging (0.825); catalogued as rs370312315; called by muse, mutect2, varscan2
- LAMA5 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 17/320 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PSG1 | c.1084G>C p.A362P | Missense Mutation (SNP) | VAF 70/592 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- AKAP11 | c.2565C>T p.D855= | Silent (SNP) | VAF 91/769 reads (12%) | catalogued as rs369631241; called by muse, mutect2, varscan2
- IRF7 | c.963G>A p.P321= (on ENST00000397566; = p.P308= on NM_001572.5) | Silent (SNP) | VAF 24/242 reads (10%) | called by muse, mutect2
- NPAS3 | c.2697C>T p.A899= (on ENST00000356141 / NM_001164749.2; = p.A867= on NM_022123.3) | Silent (SNP) | VAF 30/161 reads (19%) | catalogued as rs769448697; called by muse, mutect2, varscan2
- TBC1D12 | c.1395G>T p.L465= | Silent (SNP) | VAF 20/703 reads (3%) | called by muse, mutect2
- VSTM2L | c.285G>A p.S95= | Silent (SNP) | VAF 27/192 reads (14%) | catalogued as rs1431164832; called by muse, mutect2, varscan2
- ZC3HC1 | c.633A>G p.E211= | Silent (SNP) | VAF 98/476 reads (21%) | called by muse, mutect2, varscan2
- TTN | c.10361-4014A>C | Intron (SNP) | VAF 90/691 reads (13%) | catalogued as COSV60213277; called by muse, mutect2, varscan2
